Somatic mutation profile of tumor specimen MMRF_1030_1_BM_CD138pos (aliquot MMRF_1030_1_BM_CD138pos_T2_KAS5U_L02445) from MMRF case MMRF_1030, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.9 years (24,087 days).
Specimen MMRF_1030_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88cfa169-7f8e-4a9e-a413-cc741d2c4caa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1030_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1030_1_PB_Whole_C3_KAS5U_L02455; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e615dab7-f609-41a0-b9bf-57cddf225046

The open-access MAF lists 100 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 24, Silent 10, Intron 9, 5'UTR 6, RNA 3, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 64/149 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCAS3 | c.2575C>T p.R859W (on ENST00000390652 / NM_001353144.2; = p.R844W on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs757111288, COSV66783323; called by mutect2, varscan2
- C2orf73 | c.622dup p.T208Nfs*28 | Frame Shift Ins (INS) | VAF 52/116 reads (45%) | catalogued as rs772729186, COSV58310692; called by mutect2, varscan2
- CEACAM7 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.268); catalogued as rs1555810955; called by muse, mutect2, varscan2
- CSMD1 | c.6677C>T p.A2226V (on ENST00000520002; = p.A2225V on NM_033225.6) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as rs756664725, COSV59342193; called by muse, mutect2, varscan2
- CTSV | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs374778355; called by muse, mutect2, varscan2
- FAM170B | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1196785528, COSV100308476; called by muse, mutect2, varscan2
- FAM184A | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs371465166; called by mutect2, varscan2
- GXYLT2 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV67475072; called by muse, mutect2, varscan2
- HEPH | c.1594C>T p.P532S (on ENST00000343002; = p.P265S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV57961299; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV2-70 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs369583792; called by muse, varscan2
- IGHV2-70 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs374979633; called by muse, varscan2
- IGKV4-1 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs367963246; called by muse, mutect2, varscan2
- MED12L | c.3307G>A p.V1103M | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765305359, COSV56380842; called by muse, mutect2, varscan2
- PASD1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV64856338; called by muse, mutect2, varscan2
- PLK5 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1194098950; called by muse, mutect2
- PLXDC2 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV65906496; called by muse, mutect2, varscan2
- PTPRO | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs769300317; called by muse, varscan2
- SLC12A5 | c.1015C>T p.R339W (on ENST00000454036 / NM_001134771.2; = p.R316W on NM_020708.5) | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs373725781; called by muse, mutect2, varscan2
- SP3 | c.1997A>C p.D666A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59465793; called by mutect2, varscan2
- ZIC3 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV54975270; called by muse, mutect2
- ADD1 | c.2210C>G p.S737C | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADH1A | c.583A>T p.T195S | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD11 | c.4876C>T p.P1626S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF15 | c.995A>C p.E332A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATP5MPL | c.149-5A>T | Splice Region (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- CDK5R2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYLD | c.2473C>T p.H825Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DENND4C | c.1884C>A p.F628L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- DHX35 | c.1044_1046del p.I349del | In Frame Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel, varscan2
- EGFL7 | c.328_335del p.P110Efs*20 | Frame Shift Del (DEL) | VAF 26/35 reads (74%) | called by mutect2, varscan2
- MUC16 | c.23410G>A p.G7804R | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCBP2L | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- NHSL2 | c.842A>G p.D281G (on ENST00000510661; = p.D647G on NM_001013627.2) | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OGT | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PLIN5 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- PNMA2 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PRKCG | c.810del p.V271Wfs*8 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- RBM39 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHTN1 | c.805A>C p.N269H | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNAPC4 | c.1302G>C p.R434S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STON2 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM81 | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP38 | c.2531C>A p.S844Y | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C6orf136 | c.726T>C p.F242= (on ENST00000376473 / NM_001109938.3; = p.F108= on NM_145029.4) | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- CRYBG2 | c.2487G>A p.E829= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs978715947; called by muse, mutect2, varscan2
- IGKV4-1 | c.175T>C p.L59= | Silent (SNP) | VAF 30/32 reads (94%) | catalogued as rs771548517; called by muse, varscan2
- IGKV4-1 | c.255T>G p.P85= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as rs1471751160; called by muse, varscan2
- LRRC15 | c.802C>T p.L268= | Silent (SNP) | VAF 76/138 reads (55%) | called by muse, mutect2
- PCDHGB5 | c.1656C>T p.N552= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53956513; called by muse, mutect2, varscan2
- PIM1 | c.237G>A p.E79= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs746566492, COSV100998754, COSV65164441, COSV65164484; called by muse, mutect2, varscan2
- PLCH1 | c.4905C>T p.I1635= (on ENST00000340059 / NM_001130960.2; = p.I1627= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs556391297, COSV58204887; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1464G>A p.P488= (on ENST00000352766; = p.P409= on NM_181334.5) | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs781754419; called by muse, mutect2, varscan2
- ZNF595 | c.1308C>T p.S436= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs1553801781; called by muse, mutect2
- AF241726.1 | c.172-444625A>G | Intron (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- AFF2 | c.*2290T>G | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- ATP8A1 | c.*1945G>A | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- CACNB4 | c.*2481C>T | 3'UTR (SNP) | VAF 8/124 reads (6%) | catalogued as rs1050038800; called by muse, mutect2
- CCNQ | c.*203G>A | 3'UTR (SNP) | VAF 44/91 reads (48%) | catalogued as rs377294285; called by muse, mutect2, varscan2
- CETN3 | c.*161T>C | 3'UTR (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- CHMP2B | c.*1153T>G | 3'UTR (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- CTNND2 | c.*202C>T | 3'UTR (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- DNAAF2 | c.*126dup | 3'UTR (INS) | VAF 30/72 reads (42%) | called by mutect2, varscan2
- ELOVL6 | c.*4799dup | 3'UTR (INS) | VAF 24/55 reads (44%) | called by mutect2, pindel, varscan2
- EMC1 | c.*3297T>A | 3'UTR (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ENTPD5 | c.*297G>C | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ERCC6L2 | c.-130G>A | 5'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99998708; called by muse, mutect2
- ESYT2 | chr7:158732166 G>A | 3'Flank (SNP) | VAF 4/51 reads (8%) | catalogued as rs1056651508; called by muse, mutect2
- GASAL1 | n.580G>A | RNA (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- GFOD1 | c.*6347T>C | 3'UTR (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- GLUD2 | c.*114A>C | 3'UTR (SNP) | VAF 201/445 reads (45%) | called by muse, mutect2, varscan2
- GPSM2 | c.-137C>T | 5'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- GREM1 | c.*2918C>T | 3'UTR (SNP) | VAF 14/112 reads (13%) | catalogued as rs1292334490; called by muse, mutect2, varscan2
- HNRNPU | c.-52_-49del | 5'UTR (DEL) | VAF 55/90 reads (61%) | called by mutect2, pindel, varscan2
- IYD | c.687+1559C>A | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- IZUMO3 | c.-13G>T | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- LMO3 | c.206+6432A>T | Intron (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- LRRN4CL | c.*190G>A | 3'UTR (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- LTB | c.163-154C>T | Intron (SNP) | VAF 80/142 reads (56%) | catalogued as rs543196679; called by muse, mutect2, varscan2
- LTB | c.163-155C>T | Intron (SNP) | VAF 80/141 reads (57%) | catalogued as COSV53002321; called by muse, mutect2, varscan2
- MFN2 | c.1160+54C>T | Intron (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2
- MID1IP1 | c.-163G>A | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MKLN1 | c.*3014T>C | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- MTBP | chr8:120445355 G>T | 5'Flank (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100011866; called by muse, mutect2, varscan2
- NEUROG1 | c.*486G>A | 3'UTR (SNP) | VAF 19/75 reads (25%) | catalogued as rs1489872956; called by muse, mutect2, varscan2
- PDXK | c.143-3640C>T | Intron (SNP) | VAF 9/105 reads (9%) | catalogued as rs926160775; called by muse, mutect2
- RAB30 | chr11:82979940 G>C | 3'Flank (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- RAB35 | c.*1428C>T | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- RTL8B | c.*1532G>T | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- SASS6 | c.-97C>G | 5'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2
- SLC22A2 | c.1065-417C>A | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SLC7A14 | c.*1116del | 3'UTR (DEL) | VAF 18/50 reads (36%) | catalogued as rs972944176; called by mutect2, varscan2
- SOX3 | c.*603G>A | 3'UTR (SNP) | VAF 67/150 reads (45%) | catalogued as rs1251449814; called by muse, mutect2, varscan2
- TEAD1 | c.*3308C>A | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- USH2A | c.4627+445A>T | Intron (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- VCPIP1 | c.*923A>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs956207347, COSV60047586; called by muse, varscan2
- VENTXP1 | n.594C>T | RNA (SNP) | VAF 7/37 reads (19%) | catalogued as rs750065101; called by mutect2, varscan2
- YWHAEP5 | n.743A>C | RNA (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- ZMYND11 | c.*25C>T | 3'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as rs749996660; called by muse, mutect2, varscan2
